Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5847, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5847-01A (Primary Tumor).

[page 1 of 6]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] experienced left upper extremity partial-generalized seizure, and on imaging has a 2.5 cm, right posterior frontal lesion partially involving motor cortex and with a central enhancing zone.

OPERATIVE DIAGNOSES

Brain tumor

Operation/Specimen: A: Brain tumor, biopsy

B: Superior extent of tumor, biopsy

C: Deep posterior tumor, biopsy

PATHOLOGICAL DIAGNOSIS:

A, B, and C. Brain, site not specified/superior extent/deeper posterior, excisional biopsies:

1. Malignant astrocytoma.
2. MIB-1 proliferation index: 35%.
- See Microscopy Description and Comment.

COMMENT

The tumor is a very cellular neoplastic proliferation of glial cells. The neoplastic cells have a predominant small astrocytic phenotype. There is focal brisk mitotic activity, and the MIB-1 proliferation index is high at about 35%. There is not obvious microvascular cellular proliferation (only a few abnormal vessels on the smears) or necrosis. The tumor is a high histological grade astrocytic neoplasm. Although there is not overt microvascular cellular proliferation and/or tumor necrosis, the neoplasm's high cellularity, brisk mitotic activity and elevated MIB-1 proliferation index portend an aggressive behavior, probably more akin to a glioblastoma than to an anaplastic astrocytoma.

[page 2 of 6]
The morphological features may be correlated with clinical, imaging and operative findings and molecular testing results for their final interpretation and patient's follow up.

Electronically Signed Out

=====

PROCEDURES/ADDENDA

PCR for EGFR variant III mutation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up

to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is

commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed,

paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

are detected by gel electrophoresis. The limit of detection of this assay has

been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] as required [REDACTED]. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

[page 3 of 6]
[REDACTED]

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification [REDACTED] of methylated and unmethylated DNA sequences.

The analytic sensitivity of this assay was determined by serial dilution of

methylated positive control DNA into unmethylated DNA, and was assessed to be

1% of methylated DNA in the background of unmethylated DNA. Factors such as

the presence of >50% non-neoplastic cells in the sample, or extensive tissue

necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a

stand alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] as required by [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in [REDACTED]

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S548, D1S552, D19S219, D19S412

Results-Comments

Testing performed on DNA extracted from tumor paraffin block and a corresponding blood specimen for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

[page 4 of 6]
on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as required by [REDACTED]. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[REDACTED]

Unknown Procedure

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

[REDACTED]

Brain, right posterior frontal, biopsy [REDACTED]: WHO grade III (of IV) fibrillary astrocytoma.

See Results-Comment (below).

Results-Comments

Comment: This case was sent by patient [REDACTED] for second opinion.

Their diagnosis is written above.

Their comment reads: "Mitoses are identified in this cellular neoplasm, but

neither endothelial proliferation nor necrosis is seen."

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. "Brain tumor, biopsy," touch prep and smears: Glial neoplasm,

[page 5 of 6]
probably astrocytic, with rarely abnormal vessel. [REDACTED] Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record.

[REDACTED] [REDACTED] [REDACTED] [REDACTED]
GROSS DESCRIPTION

A.
"Brain tumor, frozen section," received fresh, one fragment, 0.8 cm across.
Semi firm, pinkish-grey, glistening. In total, A1.
B.
"Superior extent of tumor," received fresh, three fragments, 0.8 cm in aggregate. Semi firm, glistening, pinkish-grey. In total, B1.
C.
"Deeper posterior tumor," received fresh, multiple fragments, 0.8 cm in aggregate. [REDACTED] [REDACTED] [REDACTED] [REDACTED], [REDACTED]
[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates gliofibrillogenesis by the neoplastic cells (somewhat fascicular) and focally prominent macro gemistocytic morphology. A large proportion of neoplastic cells strongly over express the p53 protein. The CD163 demonstrates frequent phagocytic cells.
The CD34 depicts the vascularity of the tumor, and absence of appreciable microvascular cellular proliferation; the gemistocytic area of the neoplasm has somewhat diffuse positivity with CD34. The CD3 depicts sparse infiltrate of T lymphocytes throughout the tumor. With the MIB-1 there is a proliferation index of about 35%.

ICD-9(s):

239.6 239.6

Part A: Brain tumor, biopsy

Taken:	[REDACTED]	Received:	[REDACTED]
Stain/cnt		Block	Ordered
H/E x 1		1	[REDACTED]
TPS H/E x 1		1	[REDACTED]

Part B: Superior extent of tumor, biopsy

Taken:	[REDACTED]	Received:	[REDACTED]
Stain/cnt		Block	Ordered
H/E x 1		1	[REDACTED]

Part C: Deep posterior tumor, biopsy

[page 6 of 6]
Taken: [REDACTED]

Received: [REDACTED]

Stain/cnt	Block	Ordered	Comment
-----------	-------	---------	---------

CD163 Vector x 1	1	[REDACTED]	
------------------	---	------------	--

mCD3-DA x 1	1	[REDACTED]	
-------------	---	------------	--

CD34-DA x 1	1	[REDACTED]	
-------------	---	------------	--

EGFR VIII-curls x 1	1	[REDACTED]	
---------------------	---	------------	--

mGFAP-DA x 1	1	[REDACTED]	
--------------	---	------------	--

H/E x 1	1	[REDACTED]	
---------	---	------------	--

MGMT-curls x 1	1	[REDACTED]	
----------------	---	------------	--

MIB1-DA x 1	1	[REDACTED]	
-------------	---	------------	--

P53DO7 x 1	1	[REDACTED]	
------------	---	------------	--

Rct 1 H/E x 1	1	[REDACTED]	
---------------	---	------------	--

microdissection, x 2. Thanks.			
-------------------------------	--	--	--

Rct 2 H/E x 1	1	[REDACTED]	
---------------	---	------------	--

Do LOH also, with

*** End of Report ***

Source: NCI Genomic Data Commons file 95ed1831-189a-4101-8cd9-94d9a7e50c6a (TCGA-DU-5847.D9F2D994-5D17-46C6-A6C9-0F25703FFB22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).